Somatic mutation profile of tumor specimen MMRF_2488_1_BM_CD138pos (aliquot MMRF_2488_1_BM_CD138pos_T1_KHS5U_K15204) from MMRF case MMRF_2488, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.9 years (19,331 days).
Specimen MMRF_2488_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aaa6493-f049-47aa-a2bb-80c58cd21db1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2488_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2488_1_PB_WBC_C3_KHS5U_K15205; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a34e2fa-a056-4474-bce6-8a7f4a73786a

The open-access MAF lists 68 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 13, Intron 10, Silent 8, Nonsense Mutation 6, 5'UTR 4, 3'Flank 3, Frame Shift Del 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRNL1 | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs547896775, COSV58080761; called by muse, mutect2, varscan2
- CCDC168 | c.8051T>C p.V2684A | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101468889; called by muse, mutect2, varscan2
- CD248 | c.1253G>T p.R418I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV100256835; called by muse, mutect2, varscan2
- CELSR1 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 82/124 reads (66%) | catalogued as COSV99419456; called by muse, mutect2, varscan2
- FMNL2 | c.2749T>C p.Y917H | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs752233734; called by muse, mutect2, varscan2
- GRIA4 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 12/282 reads (4%) | catalogued as rs1163243138, COSV56918610; called by muse, mutect2
- MFSD9 | c.1216del p.Q406Rfs*13 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | catalogued as COSV99302053; called by mutect2, varscan2
- NFAM1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as rs767256709; called by muse, mutect2
- PRKAG2 | c.684+1G>A p.X228_splice | Splice Site (SNP) | VAF 11/205 reads (5%) | catalogued as rs1457532924, COSV55237353; called by muse, mutect2
- SWAP70 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 70/266 reads (26%) | catalogued as rs372544545; called by muse, mutect2, varscan2
- VAV2 | c.2233G>T p.E745* (on ENST00000371850 / NM_001134398.2; = p.E735* on NM_003371.4) | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as COSV64084734; called by muse, varscan2
- ZNF624 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1226740986, COSV60940543, COSV60940761; called by muse, mutect2, varscan2
- CFAP299 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CLNK | c.1101T>A p.N367K | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CMTR1 | c.1447del p.L483Wfs*3 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by pindel, varscan2*
- DAPK1 | c.3688C>T p.L1230F | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- DDX18 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- ITIH1 | c.297C>G p.D99E | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2
- JAKMIP1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBBP6 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- TMEM126A | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZRANB1 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANO3 | c.15A>C p.S5= | Silent (SNP) | VAF 54/232 reads (23%) | called by muse, mutect2, varscan2
- DENND5B | c.888C>T p.I296= | Silent (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- EXOSC2 | c.21T>C p.L7= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs765985454; called by muse, varscan2
- FRG1 | c.36C>T p.L12= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs73024914, COSV56996816; called by muse, mutect2
- GLCCI1 | c.147G>A p.V49= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- MIEF2 | c.1134G>A p.L378= | Silent (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
- VAX1 | c.207G>A p.A69= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1375909941, COSV53329177; called by muse, mutect2, varscan2
- ZNF420 | c.1695G>T p.G565= | Silent (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- AMOT | c.*1917T>C | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- ARL10 | c.*8277C>A | 3'UTR (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- CASP8 | chr2:201287415 T>C | 3'Flank (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- CASZ1 | c.3497+214G>A | Intron (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- CUL3 | c.-261G>A | 5'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, varscan2
- DSP | c.*553T>G | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- ESYT2 | chr7:158733545 A>T | 3'Flank (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- EYS | c.-177T>A | 5'UTR (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- GABRA2 | c.-478C>T | 5'UTR (SNP) | VAF 46/174 reads (26%) | catalogued as rs200525475; called by muse, varscan2
- HMCN2 | c.13171+13C>A | Intron (SNP) | VAF 62/277 reads (22%) | called by muse, mutect2, varscan2
- LIX1 | c.*916C>A | 3'UTR (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- MDM2 | c.*3360A>G | 3'UTR (SNP) | VAF 61/215 reads (28%) | called by muse, varscan2
- MLLT6 | c.*1462G>A | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- MMD2 | c.*906del | 3'UTR (DEL) | VAF 35/143 reads (24%) | called by mutect2, varscan2
- MYRF | c.3194+91G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs971660103, COSV53886772; called by mutect2, varscan2
- NR2F2 | c.*565G>A | 3'UTR (SNP) | VAF 17/88 reads (19%) | catalogued as rs1389494214; called by muse, mutect2, varscan2
- NRK | c.*2677A>G | 3'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, varscan2
- NUMBL | c.110-116C>T | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as rs868572916; called by mutect2, varscan2
- PCDH15 | c.*3271A>G | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- PMM1 | c.87+647G>T | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- PNMA8A | c.*861C>A | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- POU3F2 | c.*1232del | 3'UTR (DEL) | VAF 22/38 reads (58%) | catalogued as rs57487121; called by mutect2, varscan2
- PRRX1 | chr1:170663491 T>A | 5'Flank (SNP) | VAF 21/41 reads (51%) | catalogued as rs111232818; called by muse, mutect2, varscan2
- RARRES2P7 | n.47G>A | RNA (SNP) | VAF 29/99 reads (29%) | catalogued as rs979670100; called by muse, mutect2, varscan2
- SF3B2 | c.*192G>A | 3'UTR (SNP) | VAF 18/64 reads (28%) | catalogued as COSV57697207; called by muse, mutect2, varscan2
- SGSM1 | c.*194C>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- SLC5A2 | c.656-29G>C | Intron (SNP) | VAF 63/192 reads (33%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-1601T>C | 5'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- SMTN | c.51+1774T>C | Intron (SNP) | VAF 24/37 reads (65%) | catalogued as rs1194961054; called by mutect2, varscan2
- SNF8 | c.564+16C>T | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as rs560173788; called by muse, mutect2, varscan2
- STARD4 | c.398-447A>G | Intron (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- TACC2 | c.5835-2469G>A | Intron (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- TAL1 | c.*1929G>A | 3'UTR (SNP) | VAF 27/150 reads (18%) | catalogued as rs189411056; called by muse, mutect2, varscan2
- TP53AIP1 | chr11:128934952 C>T | 3'Flank (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- WDR37 | c.*769T>C | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- WTAP | c.*280A>C | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- ZNF25 | c.*179T>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- ZNF774 | c.*1017G>A | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
